Somatic mutation profile of tumor specimen TCGA-C5-A8YR-01A (aliquot TCGA-C5-A8YR-01A-12D-A37N-09) from TCGA case TCGA-C5-A8YR, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 56.6 years (20,672 days).
Specimen TCGA-C5-A8YR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7bd09baa-4eeb-4b37-9769-e96d77c7d3e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A8YR-10A (Blood Derived Normal), aliquot TCGA-C5-A8YR-10A-01D-A37N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69b9db9a-0da2-4602-83f0-5e864c313836

The open-access MAF lists 123 somatic variants for this specimen: 79 protein-altering or splice-affecting, 43 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 72, Silent 43, Nonsense Mutation 6, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AJUBA | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 18/28 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs1360361565, COSV99400882; called by muse, mutect2, varscan2
- AKAP10 | c.1163C>T p.S388L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV99855328; called by muse, varscan2
- ANO7 | c.247G>A p.G83R (on ENST00000274979; = p.G29R on NM_001001666.4) | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.573); catalogued as rs543636867, COSV51468524; called by muse, mutect2, varscan2
- ARHGEF39 | c.875C>T p.S292L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as COSV100526202, COSV100526229; called by muse, mutect2, varscan2
- ARRDC3 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV54365914, COSV99475216; called by muse, mutect2, varscan2
- ASAP3 | c.2233C>G p.Q745E | Missense Mutation (SNP) | VAF 40/43 reads (93%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs777425342, COSV100369281, COSV60877565; called by muse, mutect2, varscan2
- BIRC6 | c.10475C>G p.S3492C | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV70208581; called by muse, mutect2, varscan2
- CASP8 | c.697C>T p.R233W (on ENST00000432109 / NM_033355.3; = p.R250W on NM_001228.4) | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760898260, COSV51846938; called by muse, mutect2, varscan2
- CBL | c.570G>C p.W190C | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99875812; called by muse, mutect2, varscan2
- CDK7 | c.367C>G p.Q123E | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as COSV99841586; called by muse, mutect2, varscan2
- CDKN1A | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99781236; called by muse, mutect2, varscan2
- CDX2 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as COSV101122661; called by muse, mutect2, varscan2
- CHAD | c.1062G>C p.K354N | Missense Mutation (SNP) | VAF 41/67 reads (61%) | SIFT deleterious (0.03); PolyPhen benign (0.227); catalogued as COSV99366103; called by muse, mutect2, varscan2
- DST | c.19618C>T p.R6540C (on ENST00000361203 / NM_001374722.1; = p.R4237C on NM_015548.5) | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769340564, COSV54997851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP9 | c.943G>C p.D315H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100720088; called by muse, mutect2, varscan2
- DYNC1H1 | c.3671T>A p.I1224N | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100794638; called by muse, mutect2, varscan2
- FER1L5 | c.5586C>G p.F1862L (on ENST00000623019; = p.F1826L on NM_001293083.2) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as COSV99383204; called by muse, mutect2, varscan2
- FIGN | c.1115C>G p.S372* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as COSV100291952; called by muse, varscan2
- GEMIN6 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 44/76 reads (58%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV99931559; called by muse, varscan2
- HDAC5 | c.3278C>T p.S1093L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV99291171; called by muse, varscan2
- HIGD2A | c.68G>C p.G23A | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV51257517, COSV99220858; called by muse, mutect2, varscan2
- IL17RC | c.898G>A p.E300K (on ENST00000295981 / NM_153461.4; = p.E214K on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.194); catalogued as COSV99925623; called by muse, mutect2, varscan2
- ITGAD | c.1689C>G p.I563M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.159); catalogued as COSV66758363, COSV66759678; called by muse, mutect2, varscan2
- KATNA1 | c.562G>C p.D188H | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100167709; called by muse, mutect2, varscan2
- KMT2C | c.10262G>A p.R3421K | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV100069141; called by muse, mutect2, varscan2
- KRT12 | c.349G>A p.D117N | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as rs757586930, COSV99288840; called by muse, mutect2, varscan2
- LARP4 | c.149C>T p.S50L | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV99529121; called by muse, mutect2, varscan2
- LHX8 | c.855T>G p.S285R | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV99633320; called by muse, mutect2, varscan2
- LRFN1 | c.677C>T p.P226L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99952736; called by muse, mutect2, varscan2
- MAGED2 | c.1140C>G p.F380L | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99514444; called by muse, mutect2, varscan2
- MAN2B2 | c.1388C>T p.P463L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as COSV99577135; called by muse, mutect2, varscan2
- MAST4 | c.1812G>C p.Q604H (on ENST00000403625 / NM_001164664.2; = p.Q415H on NM_015183.3) | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99843389; called by muse, mutect2, varscan2
- MCCC1 | c.717C>A p.F239L | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV55607822, COSV99659497; called by muse, mutect2
- MEIS2 | c.617C>T p.S206F (on ENST00000561208 / NM_170675.5; = p.S193F on NM_002399.3) | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as rs770033702, COSV99576030; called by muse, mutect2, varscan2
- MFAP1 | c.550G>A p.E184K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.973); catalogued as COSV99979736; called by mutect2, varscan2
- MLH1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1553646679, COSV51620875, COSV99212364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MROH6 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1007980312, COSV99434528; called by muse, mutect2, varscan2
- MTM1 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as CM1513747, COSV100080146, COSV100080283; called by muse, mutect2, varscan2
- MYO3B | c.2092C>G p.R698G | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100509573; called by muse, mutect2, varscan2
- NKRF | c.805C>A p.L269I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.139); catalogued as COSV100441497; called by muse, mutect2, varscan2
- NPTX2 | c.1120A>G p.S374G | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs554934642, COSV99674758; called by muse, mutect2, varscan2
- OR52N2 | c.634G>C p.D212H | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100396061; called by muse, mutect2, varscan2
- OS9 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.138); catalogued as COSV57783980, COSV99232620; called by muse, mutect2, varscan2
- PAPPA | c.2668C>T p.R890W | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867106756, COSV100073308; called by muse, mutect2, varscan2
- PCDHA6 | c.2201C>T p.A734V | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs782147005, COSV65346625; called by muse, mutect2, varscan2
- PIGT | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.1); catalogued as COSV99648786; called by muse, mutect2, varscan2
- PIP4K2C | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV100723874; called by muse, mutect2, varscan2
- PJA2 | c.1854G>C p.E618D | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV100754352; called by muse, varscan2
- PLVAP | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs199706929, COSV53085595; called by muse, mutect2, varscan2
- PRB4 | c.412C>G p.P138A | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.97); catalogued as COSV99686400; called by muse, mutect2, varscan2
- QRICH1 | c.846G>C p.L282F | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100676717; called by muse, mutect2, varscan2
- RASSF8 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 29/49 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV99280743; called by muse, mutect2, varscan2
- RNF215 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.953); catalogued as rs753933810, COSV53176905; called by muse, mutect2, varscan2
- RPA1 | c.979G>A p.E327K | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.233); catalogued as COSV99627787; called by muse, mutect2, varscan2
- SCARF1 | c.912G>C p.E304D | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1195539219, COSV53959653, COSV99556936; called by muse, mutect2, varscan2
- SLC6A17 | c.1943C>G p.S648C | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV100521155; called by muse, mutect2, varscan2
- SMC6 | c.1825G>C p.E609Q | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV61172081; called by muse, mutect2, varscan2
- SMYD5 | c.255G>C p.Q85H | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.403); catalogued as COSV99242741; called by muse, mutect2, varscan2
- SOBP | c.154G>T p.E52* | Nonsense Mutation (SNP) | VAF 13/26 reads (50%) | catalogued as COSV100432927, COSV100433499; called by muse, mutect2, varscan2
- SPEN | c.9910C>G p.Q3304E | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as COSV65366909; called by muse, mutect2, varscan2
- SPOCD1 | c.3100C>G p.Q1034E | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV57093472; called by muse, mutect2, varscan2
- SPON1 | c.2312G>A p.G771E | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.666); catalogued as COSV100115454; called by muse, mutect2, varscan2
- SRCIN1 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 2/31 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as rs988338505; called by muse, mutect2
- SRSF2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as COSV57971054, COSV57971571; called by muse, mutect2, varscan2
- SVIL | c.82G>T p.G28* | Nonsense Mutation (SNP) | VAF 20/23 reads (87%) | catalogued as COSV100881104; called by muse, mutect2, varscan2
- TANGO2 | c.616G>C p.D206H | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100529988; called by muse, mutect2, varscan2
- THADA | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 44/127 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.156); catalogued as rs1479062620, COSV57681702; called by muse, mutect2, varscan2
- THOC2 | c.1907C>G p.S636* | Nonsense Mutation (SNP) | VAF 25/76 reads (33%) | catalogued as COSV99832998; called by muse, mutect2, varscan2
- TXK | c.1384G>A p.E462K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); catalogued as COSV99972252; called by muse, mutect2, varscan2
- U2AF2 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100454166; called by muse, mutect2, varscan2
- WBP11 | c.1139C>G p.S380C | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.157); catalogued as COSV99660592; called by muse, mutect2, varscan2
- WDR49 | c.1283C>T p.T428I (on ENST00000308378 / NM_001366158.1; = p.T769I on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs766258174, COSV100392086; called by muse, mutect2, varscan2
- ZC2HC1A | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as rs770959996, COSV55669695; called by muse, mutect2, varscan2
- ZNF106 | c.2865G>C p.L955F | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0.166); catalogued as rs1567014766, COSV99782348; called by muse, mutect2, varscan2
- ZNF839 | c.862G>A p.V288I (on ENST00000558850 / NM_001267827.1; = p.V404I on NM_018335.5) | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.24); PolyPhen benign (0.013); catalogued as rs757892599, COSV51755931; called by muse, mutect2, varscan2
- ADCY8 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.956); called by muse, mutect2
- DDX3X | c.372_373dup p.R125Lfs*96 (on ENST00000399959; = p.R126Lfs*96 on NM_001356.5) | Frame Shift Ins (INS) | VAF 28/57 reads (49%) | called by mutect2, pindel, varscan2
- PIM3 | c.856C>A p.Q286K | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- USP2 | c.467C>G p.S156* | Nonsense Mutation (SNP) | VAF 9/9 reads (100%) | called by muse, mutect2, varscan2
- ABCA12 | c.2388G>C p.V796= (on ENST00000272895 / NM_173076.3; = p.V478= on NM_015657.3) | Silent (SNP) | VAF 35/46 reads (76%) | catalogued as COSV99789017; called by muse, mutect2, varscan2
- ADCY6 | c.2086C>T p.L696= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs762510361, COSV100326500; called by muse, mutect2, varscan2
- AGO2 | c.495C>T p.V165= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99595434; called by muse, mutect2, varscan2
- AR | c.1752C>T p.F584= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as CM102202, COSV101017713, COSV65956639; called by muse, mutect2, varscan2
- ASZ1 | c.18G>A p.L6= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs1562864659, COSV99497843; called by muse, mutect2, varscan2
- CAGE1 | c.1384C>T p.L462= (on ENST00000512086; = p.L326= on NM_205864.3) | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs773936241, COSV99699456; called by muse, mutect2, varscan2
- COL11A2 | c.1800A>T p.R600= (on ENST00000341947 / NM_080680.3; = p.R493= on NM_080679.2) | Silent (SNP) | VAF 21/25 reads (84%) | catalogued as COSV100553612; called by muse, mutect2, varscan2
- FLT1 | c.2580G>C p.V860= | Silent (SNP) | VAF 19/29 reads (66%) | catalogued as COSV56732783, COSV56737735, COSV99150562; called by muse, mutect2, varscan2
- GABRQ | c.999C>T p.L333= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV100941149; called by muse, mutect2, varscan2
- GPR149 | c.906C>T p.F302= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV101078219; called by muse, mutect2, varscan2
- GRM3 | c.579C>T p.P193= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as COSV100862996, COSV64470865; called by muse, mutect2, varscan2
- GSR | c.744G>C p.G248= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV99645457; called by muse, mutect2, varscan2
- H1-5 | c.594G>A p.P198= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV58898866; called by muse, mutect2, varscan2
- HES4 | c.162C>G p.L54= | Silent (SNP) | VAF 34/91 reads (37%) | catalogued as COSV100515130, COSV59242962; called by muse, mutect2, varscan2
- HTRA3 | c.777C>T p.I259= | Silent (SNP) | VAF 19/34 reads (56%) | catalogued as rs144431760; called by muse, mutect2, varscan2
- IL16 | c.3183C>A p.L1061= (on ENST00000302987 / NM_172217.5; = p.L360= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/32 reads (31%) | catalogued as COSV100267226; called by muse, mutect2, varscan2
- INSRR | c.1905C>T p.L635= | Silent (SNP) | VAF 35/40 reads (88%) | catalogued as COSV100947283; called by muse, varscan2
- NECTIN1 | c.1446G>A p.G482= | Silent (SNP) | VAF 26/39 reads (67%) | catalogued as COSV50604295, COSV99871907; called by muse, mutect2, varscan2
- NLGN3 | c.291G>A p.R97= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV100704617, COSV62444876; called by muse, mutect2, varscan2
- NLRC4 | c.2742G>A p.L914= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV100707292; called by muse, mutect2, varscan2
- OSBPL7 | c.2397C>T p.I799= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as rs545253039, COSV99136593; called by muse, mutect2, varscan2
- OTOP3 | c.453C>T p.F151= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs761729278, COSV100172675; called by muse, mutect2, varscan2
- OTOP3 | c.546C>T p.V182= | Silent (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100172676; called by muse, varscan2
- OTOP3 | c.561C>T p.F187= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV60913492; called by muse, varscan2
- PCNT | c.8499C>G p.L2833= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV64029996; called by muse, mutect2, varscan2
- PDGFRB | c.1638C>T p.I546= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV99940331; called by muse, mutect2, varscan2
- PES1 | c.1122C>G p.T374= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV100073042; called by muse, mutect2, varscan2
- PIGZ | c.1704C>G p.L568= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV99433717; called by muse, mutect2, varscan2
- PIK3CB | c.993C>T p.N331= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as COSV100005360; called by muse, mutect2, varscan2
- PKP1 | c.18C>G p.L6= | Silent (SNP) | VAF 21/23 reads (91%) | catalogued as COSV99825031; called by muse, mutect2, varscan2
- PPP1R12B | c.1722C>G p.V574= | Silent (SNP) | VAF 47/57 reads (82%) | catalogued as COSV100406791; called by muse, mutect2, varscan2
- PRPF6 | c.1563C>T p.T521= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs1477256105, COSV99411662; called by muse, mutect2, varscan2
- PRUNE2 | c.831C>T p.I277= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100944325; called by muse, mutect2, varscan2
- RIN3 | c.1882C>T p.L628= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs780866567, COSV99378791; called by muse, mutect2, varscan2
- RTCA | c.87C>T p.L29= | Silent (SNP) | VAF 49/53 reads (92%) | catalogued as rs1026941625, COSV99559647; called by muse, mutect2, varscan2
- SLC39A11 | c.426G>A p.R142= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV99722683; called by muse, mutect2, varscan2
- SLITRK5 | c.1390C>T p.L464= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs190934260, COSV61528007; called by muse, mutect2, varscan2
- SNRNP40 | c.315G>A p.L105= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as COSV99745174; called by muse, mutect2, varscan2
- SSH2 | c.117G>A p.E39= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs913003900, COSV99281652; called by muse, mutect2, varscan2
- TRPT1 | c.627C>G p.L209= (on ENST00000317459 / NM_001160393.1; = p.L160= on NM_031472.4) | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as COSV99655721; called by muse, mutect2, varscan2
- USP2 | c.381C>T p.I127= | Silent (SNP) | VAF 10/12 reads (83%) | catalogued as COSV99489442; called by muse, mutect2, varscan2
- ZNF304 | c.1302C>G p.L434= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99988494; called by muse, mutect2, varscan2
- ZNF536 | c.1182C>G p.V394= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as COSV100834897, COSV62822780; called by muse, mutect2, varscan2
- LPAL2 | n.373G>C | RNA (SNP) | VAF 12/32 reads (38%) | catalogued as rs1216683740; called by muse, mutect2, varscan2
